Somatic mutation profile of tumor specimen TCGA-BR-A4J7-01A (aliquot TCGA-BR-A4J7-01A-31D-A25D-08) from TCGA case TCGA-BR-A4J7, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 49.1 years (17,932 days).
Specimen TCGA-BR-A4J7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f627d49e-b594-473e-8a6f-301c89a9caa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J7-10A (Blood Derived Normal), aliquot TCGA-BR-A4J7-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63d3e8a2-af11-4ae9-9e04-15e81a017c35

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Nonsense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8911C>T p.Q2971* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs1565607653, CM160311, COSV53725721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.10951C>T p.R3651* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as rs769929539, COSV59438495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP8B2 | c.2309T>G p.L770R (on ENST00000672630; = p.L737R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV59244690; called by muse, mutect2, varscan2
- BACH2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57584199; called by muse, mutect2
- CCDC110 | c.1135A>G p.R379G | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV56869339; called by muse, mutect2
- COL11A1 | c.3725C>A p.P1242Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV62172715; called by muse, mutect2
- DLGAP3 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs762482299, COSV52391347, COSV99333045; called by muse, mutect2, varscan2
- FANCD2 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV99810713; called by muse, mutect2
- HECTD4 | c.12323C>A p.T4108N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV101106975; called by muse, mutect2
- HNRNPA1 | c.991G>A p.G331R (on ENST00000340913 / NM_031157.4; = p.G279R on NM_002136.4) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.755); catalogued as COSV52935635; called by muse, mutect2
- KCNS3 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.077); catalogued as COSV58405250; called by muse, mutect2
- KRTAP10-2 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV59951594; called by muse, mutect2, varscan2
- LRRC7 | c.3998A>G p.N1333S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.129); catalogued as COSV50410442; called by muse, mutect2, varscan2
- MAP2K7 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156815343, COSV67607577, COSV67607584; called by muse, mutect2, varscan2
- NPSR1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62196404; called by muse, mutect2
- PASD1 | c.72T>G p.I24M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV64854059; called by muse, mutect2
- PCDH11Y | c.584C>A p.A195D (on ENST00000400457 / NM_032973.2; = p.A184D on NM_032971.3) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99290933; called by muse, mutect2, varscan2
- PLCL1 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV70820990; called by muse, mutect2
- PLEC | c.10856G>A p.R3619H (on ENST00000322810 / NM_201380.4; = p.R3509H on NM_000445.5) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs548876454, COSV59603009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNMT | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs111272760; called by muse, mutect2, varscan2
- REV3L | c.1144A>G p.I382V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100724992, COSV100725026; called by muse, mutect2
- SNAI2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV50078639; called by muse, mutect2, varscan2
- TAGAP | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV57850500; called by muse, mutect2
- TBC1D31 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs139812181; called by muse, mutect2, varscan2
- USP2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1344550169, COSV52726944; called by muse, mutect2
- VIRMA | c.5434C>T p.R1812* | Nonsense Mutation (SNP) | VAF 24/241 reads (10%) | catalogued as rs776109633, COSV52581680; called by muse, mutect2
- XPR1 | c.1064T>A p.M355K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV62554452; called by muse, mutect2, varscan2
- TTN | c.3355G>A p.G1119S (on ENST00000591111; = p.G1073S on NM_003319.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A3 | c.6264G>A p.P2088= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1156803322, COSV55079579, COSV99797960; called by muse, mutect2, varscan2
- CPSF4 | c.747C>T p.G249= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs767929343, COSV52853758; called by muse, varscan2
- GDF6 | c.273C>T p.R91= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV54622739; called by muse, mutect2, varscan2
- GLIS1 | c.1248C>T p.G416= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV56543635; called by muse, mutect2
- KCNB2 | c.2433C>T p.D811= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs150484780; called by muse, mutect2, varscan2
- NOS1 | c.3144C>T p.L1048= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs374883833; called by muse, mutect2, varscan2
- OR5AR1 | c.441C>A p.G147= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV57255649; called by muse, mutect2
- PARD6B | c.90T>C p.F30= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV65404071; called by muse, mutect2
- PLXNC1 | c.3633C>T p.N1211= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs951586924, COSV51569299; called by muse, mutect2, varscan2
- PTPRD | c.756C>T p.S252= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs765489687, COSV61928020; called by muse, mutect2, varscan2
- TMEM185A | c.717C>T p.N239= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1240176180; called by muse, mutect2, varscan2
- TPO | c.1497G>A p.P499= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs776864359, COSV61094421; called by muse, mutect2, varscan2
- ZNF480 | c.129C>T p.C43= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV57994583; called by muse, mutect2
- AL590867.2 | n.43G>A | RNA (SNP) | VAF 16/101 reads (16%) | catalogued as rs758305264; called by muse, mutect2, varscan2
